Somatic mutation profile of tumor specimen 0DJXQ9 from CCDI case PBBXEU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 5.3 years (1,918 days).
Specimen 0DJXQ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b5de8fc-ffa4-4953-a780-1b872c030e7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJXRJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7898d4c-0e4e-4c20-84c4-d5a1422f174c

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEGF8 | c.2654G>A p.G885E (on ENST00000251268 / NM_001271938.2; = p.G818E on NM_001410.3) | Missense Mutation (SNP) | VAF 186/411 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as rs771983135, COSV52099985; called by muse, mutect2, varscan2
- MEX3D | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs774419041; called by muse, mutect2, varscan2
- NRXN1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 29/392 reads (7%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.74); catalogued as rs752469666, COSV68000408; called by muse, mutect2
- PCGF5 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as rs1232977395, COSV60237735; called by muse, mutect2, varscan2
- PEX11B | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 48/511 reads (9%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.561); catalogued as rs782067337; called by muse, mutect2
- PLXNB1 | c.3485C>T p.P1162L | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs764453804, COSV56489997; called by muse, mutect2, varscan2
- TNR | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 174/528 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757472943, COSV54878444; called by muse, mutect2, varscan2
- ANO1 | c.1178C>A p.S393* | Nonsense Mutation (SNP) | VAF 135/404 reads (33%) | called by muse, mutect2, varscan2
- CENPN | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 15/370 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2
- CLDN12 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 25/579 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NELL1 | c.858G>T p.W286C | Missense Mutation (SNP) | VAF 148/395 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A9 | c.340-99C>T | Intron (SNP) | VAF 57/248 reads (23%) | catalogued as rs749180360, COSV99361533; called by muse, mutect2, varscan2
- TTC38 | c.*71G>C | 3'UTR (SNP) | VAF 56/125 reads (45%) | called by muse, mutect2, varscan2
